Somatic mutation profile of tumor specimen PCProject_0056_T1_WES (aliquot PCProject_0056_T1_WES_1) from CMI case PCProject_0056, project CMI-MPC: Count Me In (CMI): The Metastatic Prostate Cancer (MPC) Project. Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 71.3 years (26,033 days).
Specimen PCProject_0056_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Prostate; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a14281b1-273e-48db-8273-38e07a4503eb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen PCProject_0056_SALIVA (DNA), aliquot PCProject_0056_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2e800933-67c0-4b55-b970-83c0e0d6d74d

The open-access MAF lists 81 somatic variants for this specimen: 58 protein-altering or splice-affecting, 16 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, Silent 16, Intron 4, Frame Shift Del 3, RNA 2, In Frame Del 1, Nonsense Mutation 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.403T>C p.C135R | Missense Mutation (SNP) | VAF 106/513 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519975, COSV52674321, COSV52706302, COSV52827707; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC12 | c.2005G>A p.D669N | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.314); catalogued as COSV100253379; called by muse, mutect2, varscan2
- ACSL1 | c.1240C>T p.R414W | Missense Mutation (SNP) | VAF 76/410 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs755845769, COSV99860839; called by muse, mutect2, varscan2
- AKR1C3 | c.947A>G p.N316S | Missense Mutation (SNP) | VAF 9/121 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs868947776; called by muse, mutect2
- APC | c.3964G>T p.E1322* | Nonsense Mutation (SNP) | VAF 100/489 reads (20%) | catalogued as COSV57325414, COSV57354660, COSV57393116, COSV99964740; called by muse, mutect2, varscan2
- AQR | c.1150C>T p.L384F | Missense Mutation (SNP) | VAF 40/259 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.714); catalogued as COSV50041490; called by muse, mutect2, varscan2
- BSN | c.7811C>T p.A2604V | Missense Mutation (SNP) | VAF 150/717 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs775235960; called by muse, mutect2, varscan2
- DNAH3 | c.7389C>A p.N2463K | Missense Mutation (SNP) | VAF 78/390 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.486); catalogued as rs756582607, COSV99766313; called by muse, mutect2, varscan2
- DNMT1 | c.1744C>G p.R582G | Missense Mutation (SNP) | VAF 161/764 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61582692; called by muse, mutect2, varscan2
- FEZ2 | c.961C>G p.L321V | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59906175; called by muse, mutect2, varscan2
- IRF3 | c.1021C>T p.R341C | Missense Mutation (SNP) | VAF 131/841 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as rs760057796, COSV99881800; called by muse, mutect2, varscan2
- LRRTM3 | c.988T>C p.F330L | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.318); catalogued as COSV100791912; called by muse, mutect2, varscan2
- OR4C13 | c.515T>G p.I172R | Missense Mutation (SNP) | VAF 40/158 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs781828746; called by muse, mutect2, varscan2
- OR4M1 | c.734A>G p.H245R | Missense Mutation (SNP) | VAF 28/222 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs771752552; called by muse, mutect2, varscan2
- PHF2 | c.2705C>T p.A902V | Missense Mutation (SNP) | VAF 90/579 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.341); catalogued as rs757419993; called by muse, mutect2, varscan2
- PLEC | c.4799C>T p.A1600V (on ENST00000322810 / NM_201380.4; = p.A1490V on NM_000445.5) | Missense Mutation (SNP) | VAF 281/1978 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.01); catalogued as rs1554703096; called by muse, mutect2, varscan2
- RTL10 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 161/955 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0.022); catalogued as rs1569058709, COSV60735707; called by muse, mutect2, varscan2
- RWDD2B | c.803C>T p.T268M | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs772311092, COSV54501721; called by muse, varscan2
- RYBP | c.572del p.S191Wfs*109 | Frame Shift Del (DEL) | VAF 225/1292 reads (17%) | catalogued as COSV72180442; called by mutect2, pindel, varscan2
- SDK1 | c.3835G>A p.A1279T | Missense Mutation (SNP) | VAF 24/452 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.461); catalogued as rs1020652566, COSV67373540; called by muse, mutect2
- SMOX | c.331C>T p.R111C | Missense Mutation (SNP) | VAF 192/1751 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs760624917; called by muse, mutect2, varscan2
- SPATA18 | c.1291C>A p.Q431K | Missense Mutation (SNP) | VAF 20/190 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs758594533; called by muse, varscan2
- SPATA31A6 | c.1424G>A p.R475H | Missense Mutation (SNP) | VAF 215/1337 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as rs1229645756, COSV60533095; called by muse, mutect2, varscan2
- TMEM151A | c.640G>A p.A214T | Missense Mutation (SNP) | VAF 114/778 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.108); catalogued as COSV59175272; called by muse, mutect2, varscan2
- UNC80 | c.7106T>C p.V2369A | Missense Mutation (SNP) | VAF 44/202 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs768137134; called by mutect2, varscan2
- ZFPL1 | c.392G>T p.G131V | Missense Mutation (SNP) | VAF 57/346 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51869185, COSV99297892; called by muse, mutect2, varscan2
- ZNF317 | c.1108G>A p.A370T | Missense Mutation (SNP) | VAF 86/569 reads (15%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.708); catalogued as rs866620454; called by muse, mutect2, varscan2
- ABCC2 | c.4061C>T p.A1354V | Missense Mutation (SNP) | VAF 100/773 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- AC011005.1 | c.940G>T p.A314S | Missense Mutation (SNP) | VAF 124/738 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- CCDC181 | c.308C>G p.S103C | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- CITED4 | c.508T>A p.F170I | Missense Mutation (SNP) | VAF 98/616 reads (16%) | SIFT tolerated (0.87); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- COL1A2 | c.596G>C p.G199A | Missense Mutation (SNP) | VAF 64/186 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DHX9 | c.2857A>C p.T953P | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- ENDOD1 | c.1135C>G p.L379V | Missense Mutation (SNP) | VAF 145/438 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- FILIP1L | c.439G>A p.V147M | Missense Mutation (SNP) | VAF 33/243 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- GPR176 | c.536C>T p.A179V | Missense Mutation (SNP) | VAF 92/475 reads (19%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- IL11RA | c.580A>T p.N194Y | Missense Mutation (SNP) | VAF 257/1583 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ITPRIP | c.820A>G p.N274D | Missense Mutation (SNP) | VAF 53/264 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KSR1 | c.1483C>T p.H495Y (on ENST00000644974 / NM_001367810.1; = p.H358Y on NM_014238.2) | Missense Mutation (SNP) | VAF 28/251 reads (11%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- LIN28A | c.51_86del p.E18_A29del | In Frame Del (DEL) | VAF 90/900 reads (10%) | called by mutect2, pindel
- MGMT | c.563A>G p.N188S (on ENST00000306010; = p.N157S on NM_002412.5) | Missense Mutation (SNP) | VAF 168/974 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- MOGS | c.1708C>G p.P570A | Missense Mutation (SNP) | VAF 55/315 reads (17%) | SIFT tolerated (0.76); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- MYT1L | c.901A>G p.M301V | Missense Mutation (SNP) | VAF 83/429 reads (19%) | SIFT tolerated, low confidence (0.98); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- NFKBIE | c.330A>C p.Q110H | Missense Mutation (SNP) | VAF 141/841 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- OMA1 | c.242G>T p.G81V | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR7D4 | c.725G>T p.G242V | Missense Mutation (SNP) | VAF 40/327 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- PCDHB14 | c.1940A>T p.N647I | Missense Mutation (SNP) | VAF 166/957 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); called by mutect2, varscan2
- PGBD1 | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 97/437 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RELN | c.338G>A p.G113E | Missense Mutation (SNP) | VAF 103/714 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SGCG | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 97/508 reads (19%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- SPATS2 | c.1181G>C p.S394T | Missense Mutation (SNP) | VAF 129/730 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ST7 | c.654A>T p.R218S | Missense Mutation (SNP) | VAF 47/206 reads (23%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- STAG1 | c.2200G>C p.V734L | Missense Mutation (SNP) | VAF 33/164 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TCHH | c.2242T>C p.W748R | Missense Mutation (SNP) | VAF 108/639 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- TEX51 | c.450C>G p.D150E (on ENST00000643416; = p.D126E on NM_001322244.2) | Missense Mutation (SNP) | VAF 99/485 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TMPRSS11A | c.248del p.N83Ifs*3 | Frame Shift Del (DEL) | VAF 10/78 reads (13%) | called by pindel, varscan2
- TMPRSS5 | c.132del p.M45Cfs*24 | Frame Shift Del (DEL) | VAF 136/954 reads (14%) | called by mutect2, pindel, varscan2
- TPCN2 | c.1140G>T p.M380I | Missense Mutation (SNP) | VAF 219/694 reads (32%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNDP1 | c.480A>C p.G160= | Silent (SNP) | VAF 99/426 reads (23%) | catalogued as rs747787545; called by muse, mutect2, varscan2
- ENGASE | c.919C>A p.R307= | Silent (SNP) | VAF 34/584 reads (6%) | catalogued as COSV56135764; called by muse, mutect2
- GALNT6 | c.597C>T p.S199= | Silent (SNP) | VAF 195/1147 reads (17%) | catalogued as rs1234082982, COSV100695243, COSV100695686; called by muse, mutect2, varscan2
- IGLL1 | c.541C>T p.L181= | Silent (SNP) | VAF 245/1625 reads (15%) | called by muse, mutect2, varscan2
- KMT2A | c.5022C>G p.P1674= | Silent (SNP) | VAF 43/234 reads (18%) | called by muse, mutect2, varscan2
- MAMDC2 | c.936A>T p.G312= | Silent (SNP) | VAF 25/140 reads (18%) | catalogued as rs1351414746; called by muse, mutect2, varscan2
- MUC13 | c.654G>A p.G218= | Silent (SNP) | VAF 29/148 reads (20%) | catalogued as COSV60701453; called by muse, mutect2, varscan2
- NRCAM | c.2145G>A p.V715= (on ENST00000379028 / NM_001371124.1; = p.V699= on NM_005010.4 and 21 other RefSeq transcripts) | Silent (SNP) | VAF 194/1222 reads (16%) | called by muse, mutect2, varscan2
- OLIG3 | c.489C>A p.T163= | Silent (SNP) | VAF 88/488 reads (18%) | called by muse, mutect2, varscan2
- P2RY12 | c.798T>C p.D266= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as rs752154675; called by muse, mutect2, varscan2
- PCDHB7 | c.1569C>T p.A523= | Silent (SNP) | VAF 811/2155 reads (38%) | catalogued as rs782464666; called by muse, mutect2, varscan2
- PIGT | c.1569C>T p.S523= | Silent (SNP) | VAF 184/1229 reads (15%) | called by muse, mutect2, varscan2
- SPHK1 | c.789G>A p.L263= (on ENST00000392496 / NM_001355139.2; = p.L277= on NM_021972.4) | Silent (SNP) | VAF 40/1182 reads (3%) | called by muse, mutect2
- SSC5D | c.1266C>G p.S422= | Silent (SNP) | VAF 118/542 reads (22%) | called by muse, mutect2, varscan2
- TAOK3 | c.372C>T p.I124= | Silent (SNP) | VAF 13/101 reads (13%) | catalogued as rs1052289063, COSV66825717; called by muse, mutect2, varscan2
- USP14 | c.1125G>A p.K375= | Silent (SNP) | VAF 18/104 reads (17%) | catalogued as rs1319142991; called by muse, mutect2, varscan2
- B4GALNT1 | chr12:57623035 A>T | 3'Flank (SNP) | VAF 97/418 reads (23%) | catalogued as COSV57543867; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.1742+46G>C | Intron (SNP) | VAF 20/74 reads (27%) | catalogued as rs1354260579; called by muse, mutect2
- DTX2 | c.1151-274G>A | Intron (SNP) | VAF 6/46 reads (13%) | called by mutect2, varscan2
- FAM172BP | n.963C>A | RNA (SNP) | VAF 15/149 reads (10%) | called by muse, mutect2, varscan2
- GTF2IRD2P1 | n.2217C>A | RNA (SNP) | VAF 277/1326 reads (21%) | called by muse, mutect2, varscan2
- MUC13 | c.1215-31A>G | Intron (SNP) | VAF 40/145 reads (28%) | called by muse, mutect2, varscan2
- SEPTIN5 | c.55-2279A>C | Intron (SNP) | VAF 52/984 reads (5%) | catalogued as rs768965870; called by muse, mutect2
